Somatic mutation profile of tumor specimen TARGET-10-PARGLW-09A (aliquot TARGET-10-PARGLW-09A-01D) from TARGET case TARGET-10-PARGLW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.3 years (3,744 days).
Specimen TARGET-10-PARGLW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ea0c6ff-6cfe-4764-ba9d-c2290ddaf01e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGLW-10A (Blood Derived Normal), aliquot TARGET-10-PARGLW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22b032ff-f286-45df-8e15-2c1742d64962

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 3, RNA 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTN | c.54925C>T p.R18309* (on ENST00000591111; = p.R10885* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/44 reads (59%) | catalogued as rs1559598775, COSV59971331; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APBB1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs778153421; called by muse, mutect2, varscan2
- CACNA1E | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1468245846, COSV62390167; called by muse, mutect2, varscan2
- HAVCR1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as rs781388022, COSV59400444; called by muse, mutect2, varscan2
- KMT2D | c.954+1G>A p.X318_splice | Splice Site (SNP) | VAF 40/96 reads (42%) | catalogued as CS119953; called by muse, mutect2, varscan2
- USP28 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as rs1389829322, COSV50188515; called by muse, mutect2, varscan2
- AP3B2 | c.1910G>A p.G637D | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CENPE | c.7199A>T p.K2400M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- KIAA1522 | c.2560C>T p.R854* (on ENST00000373480 / NM_001198972.2; = p.R913* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- SPSB4 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZPR1 | c.1114C>A p.L372M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ABCA10 | c.3936C>A p.G1312= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- ENPP2 | c.1425C>T p.H475= (on ENST00000075322 / NM_001040092.3; = p.H527= on NM_006209.5) | Silent (SNP) | VAF 76/165 reads (46%) | catalogued as rs936128139, COSV50047627; called by muse, mutect2, varscan2
- VCAM1 | c.1068C>T p.S356= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs781257237, COSV54118934; called by muse, mutect2, varscan2
- ZBTB45 | c.219G>A p.P73= | Silent (SNP) | VAF 59/110 reads (54%) | catalogued as rs745594799, COSV100657818; called by muse, mutect2, varscan2
- LINC00955 | n.716C>T | RNA (SNP) | VAF 73/141 reads (52%) | called by muse, mutect2, varscan2
- RNA5SP283 | chr9:62801900 C>A | 3'Flank (SNP) | VAF 3/13 reads (23%) | catalogued as rs970635542; called by muse, mutect2
